Somatic mutation profile of tumor specimen C3L-08242-01 (aliquot CPT0485480006) from CPTAC case C3L-08242, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 68.1 years (24,888 days).
Specimen C3L-08242-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c48770c1-f429-4606-b216-d3fb71113127.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08242-32 (Blood Derived Normal), aliquot CPT0485630003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3ccdc74-2160-432d-a797-7639c0a83b03

The open-access MAF lists 102 somatic variants for this specimen: 84 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 16, Nonsense Mutation 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.3247C>T p.R1083C (on ENST00000372530 / NM_001198934.2; = p.R1055C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/367 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.567); catalogued as rs41281804; called by muse, mutect2
- AOC1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 38/389 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as rs760892433, COSV62866677; called by muse, mutect2
- CHST2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs1046343311; called by muse, mutect2
- CNTN6 | c.2768G>C p.W923S | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63184873; called by muse, mutect2
- EHD1 | c.669G>C p.Q223H | Missense Mutation (SNP) | VAF 14/381 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs1339079513; called by muse, mutect2
- ENPP6 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs143413078; called by muse, mutect2
- FAM71A | c.1559G>C p.S520T | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs927382011; called by muse, mutect2
- FAM83A | c.120C>A p.D40E | Missense Mutation (SNP) | VAF 12/436 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99414770; called by muse, mutect2
- FAT4 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748505773, COSV67896183; called by muse, mutect2
- FGB | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.377); catalogued as rs121909620, CM920275; ClinVar: other; called by muse, mutect2
- GBA | c.938A>G p.H313R | Missense Mutation (SNP) | VAF 14/494 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs747591577; called by muse, mutect2
- GHITM | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs964858602; called by muse, mutect2
- ITIH6 | c.3832C>A p.L1278M | Missense Mutation (SNP) | VAF 36/431 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV99513424; called by muse, mutect2
- KCND2 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100476726; called by muse, mutect2
- MSANTD2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 31/493 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.817); catalogued as rs1282237433; called by muse, mutect2
- PCDHB1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1554267169, COSV60630142; called by muse, mutect2
- PREX2 | c.3586G>C p.G1196R | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV55776687; called by muse, mutect2, varscan2
- PSG11 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs758939809, COSV60454132; called by muse, varscan2
- SNED1 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs1489580212; called by muse, mutect2
- UGT2B10 | c.621G>T p.M207I | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1007082869; called by muse, mutect2
- UNC5B | c.2641C>T p.R881W | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138249629; called by muse, mutect2, varscan2
- URGCP | c.2092G>A p.V698I (on ENST00000453200 / NM_001077663.3; = p.V689I on NM_017920.4) | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs780354948; called by muse, mutect2, varscan2
- ADGRG4 | c.8520A>T p.K2840N | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- ANLN | c.745A>C p.N249H | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- ARMC10 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ATP6V0A1 | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C2CD4A | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CCDC185 | c.1537A>T p.K513* | Nonsense Mutation (SNP) | VAF 13/353 reads (4%) | called by muse, mutect2
- CCER1 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.381); called by muse, mutect2
- CD300A | c.767G>C p.S256T | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- CDH17 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CIART | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.346); called by muse, mutect2
- CLC | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2
- COBLL1 | c.2400G>T p.E800D (on ENST00000392717; = p.E762D on NM_014900.5) | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- COL16A1 | c.456C>A p.D152E | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- GABRG2 | c.625T>C p.S209P | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- GPRASP2 | c.1751G>A p.C584Y | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRPR | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GTPBP1 | c.922A>C p.T308P | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HID1 | c.1714C>G p.P572A | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IQSEC3 | c.2949G>C p.E983D (on ENST00000538872 / NM_001170738.2; = p.E680D on NM_015232.1) | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2
- IRGC | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.153); called by muse, mutect2
- ITPR2 | c.4190G>C p.C1397S | Missense Mutation (SNP) | VAF 11/295 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- KASH5 | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- KBTBD11 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 26/474 reads (5%) | called by muse, mutect2
- KHDRBS3 | c.157A>T p.N53Y | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- KIAA1549L | c.3539T>A p.L1180Q (on ENST00000321505; = p.L1477Q on NM_012194.3) | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRBA1 | c.1540G>T p.V514L | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2
- LAMA2 | c.6125G>A p.R2042K | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.726); called by muse, mutect2
- LAMA2 | c.6716G>T p.R2239I | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2
- LENG9 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LIPJ | c.28T>A p.W10R | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.134); called by muse, mutect2
- LRIF1 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.168); called by muse, mutect2
- LRRTM1 | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2
- LRRTM1 | c.1450T>A p.S484T | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.76); called by muse, mutect2
- MAP3K1 | c.4303G>T p.V1435F | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- MAP6 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 22/435 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- MMP24 | c.653C>A p.A218E | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRE11 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- MSH5 | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- MUC4 | c.16065G>T p.W5355C (on ENST00000463781 / NM_018406.7; = p.W1119C on NM_004532.6) | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- NFASC | c.3703G>A p.A1235T (on ENST00000339876 / NM_001378329.1; = p.A1164T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2
- NLRP1 | c.3400C>G p.Q1134E | Missense Mutation (SNP) | VAF 13/363 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2
- NLRP2 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NYAP1 | c.420C>G p.S140R | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.277); called by muse, mutect2
- OLFM4 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- PKD1L1 | c.6779A>G p.H2260R | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PPP1R17 | c.206_216del p.P69Hfs*15 | Frame Shift Del (DEL) | VAF 26/290 reads (9%) | called by mutect2, pindel
- RIPOR1 | c.895C>G p.P299A (on ENST00000379312 / NM_001193522.2; = p.P295A on NM_024519.4) | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- RNF34 | c.1004G>C p.C335S | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ROBO2 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 13/419 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); called by muse, mutect2
- SERPINB1 | c.98T>A p.F33Y | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLAIN1 | c.1301C>T p.S434L (on ENST00000466548; = p.S171L on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SLC15A3 | c.1039C>G p.P347A | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLIT2 | c.1432T>G p.C478G | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPAG6 | c.792T>G p.D264E | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); called by muse, mutect2
- SPRED3 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.937); called by muse, mutect2
- TENT4A | c.1953G>C p.L651F | Missense Mutation (SNP) | VAF 22/472 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM39A | c.844A>C p.N282H | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- UBAP2L | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- ZNF335 | c.3989A>C p.Q1330P | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF469 | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 12/412 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- ZNF646 | c.4038G>C p.R1346S | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2
- ZNF764 | c.120G>T p.W40C | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- AC099489.1 | c.3550A>C p.R1184= | Silent (SNP) | VAF 19/282 reads (7%) | called by muse, mutect2
- C20orf144 | c.132G>A p.R44= | Silent (SNP) | VAF 15/286 reads (5%) | called by muse, mutect2
- CHST2 | c.72C>A p.A24= | Silent (SNP) | VAF 29/374 reads (8%) | called by muse, mutect2
- ERMP1 | c.159C>T p.S53= | Silent (SNP) | VAF 25/444 reads (6%) | catalogued as rs1291288483; called by muse, mutect2
- HFE | c.960G>A p.L320= | Silent (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- IQUB | c.186G>A p.E62= | Silent (SNP) | VAF 15/306 reads (5%) | called by muse, mutect2
- KBTBD11 | c.174G>T p.A58= | Silent (SNP) | VAF 30/476 reads (6%) | called by muse, mutect2
- LPA | c.5211T>C p.T1737= | Silent (SNP) | VAF 16/340 reads (5%) | catalogued as rs1475938696; called by muse, mutect2
- MARCHF9 | c.528C>T p.S176= | Silent (SNP) | VAF 25/401 reads (6%) | called by muse, mutect2
- OBSL1 | c.5481G>T p.V1827= | Silent (SNP) | VAF 24/387 reads (6%) | called by muse, mutect2
- PCDHA7 | c.2016C>T p.S672= | Silent (SNP) | VAF 14/330 reads (4%) | catalogued as rs781833961, COSV65340860; called by muse, mutect2
- PVR | c.39G>T p.L13= | Silent (SNP) | VAF 16/364 reads (4%) | called by muse, mutect2
- SMOX | c.192G>C p.V64= | Silent (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- ZNF366 | c.495G>A p.T165= | Silent (SNP) | VAF 18/433 reads (4%) | catalogued as rs1217484258, COSV59214170; called by muse, mutect2
- ZNF691 | c.249T>A p.T83= (on ENST00000372502; = p.T52= on NM_015911.3) | Silent (SNP) | VAF 22/370 reads (6%) | called by muse, mutect2
- ZNF784 | c.900G>C p.G300= | Silent (SNP) | VAF 20/379 reads (5%) | called by muse, mutect2
- COX4I1 | c.374-259G>T | Intron (SNP) | VAF 18/331 reads (5%) | called by muse, mutect2
- ELF5 | c.385+11A>G | Intron (SNP) | VAF 26/394 reads (7%) | called by muse, mutect2
